Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3672, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3672-01A (Primary Tumor).

Diagnosis:

Right-sided hemicolectomy preparation shows tumor-free oral and aboral resection margins and includes an ulcerated, moderately differentiated adenocarcinoma of the transverse colon with infiltration of the perimuscular fatty tissue (G2, pT3).

Follow-up report:

After acetone clearing, 21 lymph nodes up to 0.7 cm in size can be prepared in the pericolic fatty tissue adjoining the tumor.

Of these, one lymph node shows metastatic infiltrates of the previously diagnosed adenocarcinoma or colon carcinoma.

In conclusion, to summarize, the disease is staged as pT3 pN1 (4/21) L0 V0 R0.

Source: NCI Genomic Data Commons file bc560667-11da-4a45-9654-d83d17d60cc9 (TCGA-AA-3672.72117EA9-8089-4922-9732-D532B6AC5D94.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).